Somatic mutation profile of tumor specimen 0DR3MD from CCDI case PBCFZC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 13.0 years (4,731 days).
Specimen 0DR3MD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ae61637-4cf1-4776-bf75-a359f552f88a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR3L4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ad5a9da-f7a4-4b51-bd6c-0088adf2f637

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, In Frame Del 1, 5'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRYL | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 189/361 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51958434, COSV99977903; called by muse, mutect2
- TMEM215 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 58/439 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV61363293; called by muse, mutect2, varscan2
- NEURL4 | c.2878G>A p.V960M | Missense Mutation (SNP) | VAF 151/424 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SLC7A6OS | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 36/548 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- TTC25 | c.436_447del p.S146_S149del | In Frame Del (DEL) | VAF 48/334 reads (14%) | called by mutect2, pindel, varscan2
- FLNA | c.7668C>T p.D2556= (on ENST00000369850 / NM_001110556.2; = p.D2548= on NM_001456.3) | Silent (SNP) | VAF 69/602 reads (11%) | catalogued as rs782784577, COSV61043567; called by muse, mutect2, varscan2
- CALM3 | chr19:46601047 G>T | 5'Flank (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
